CPTAC case C3N-01656 — Kidney — Adenomas and Adenocarcinomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Adenomas and Adenocarcinomas; Primary site: Kidney. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/2a901029-a9d7-41a7-829d-b9c102a6d157

Demographics
Sex at birth: male; Race: white; Year of birth: 1948; Vital status: Alive; Country of birth: Poland.

Diagnoses (1)
1. Renal cell carcinoma, NOS: ICD-O-3 morphology code: 8312/3; Tissue or organ of origin: Kidney, NOS; Site of resection or biopsy: Kidney, NOS; Age at diagnosis: 68.9 years (25,181 days); Year of diagnosis: 2017; AJCC staging edition: 7th; AJCC clinical M: MX; AJCC pathologic T: T3a; AJCC pathologic N: NX; AJCC pathologic M: MX; AJCC pathologic stage: Stage III; Tumor grade: G2; Residual disease: RX; Days to last known disease status: 1,880 days (5.1 years); Progression or recurrence: yes; Days to last follow up: 1,880 days (5.1 years); Tumor focality: Unifocal.
   Pathology details: Greatest tumor dimension: 8 cm (a second GDC size field records 3 cm); Lymph node involvement: Negative; Lymph nodes positive: 0; Lymph nodes tested: 0; Margin status: Uninvolved; Sarcomatoid present: No.

Follow-up (6 entries)
- Days to follow up: 349 days; Disease response: Tumor Free.
- Days to follow up: 714 days (2.0 years); Disease response: With Tumor.
- Days to follow up: 1,230 days (3.4 years); Disease response: With Tumor.
- Days to follow up: 1,532 days (4.2 years); Disease response: With Tumor.
- Days to follow up: 1,532 days (4.2 years); Disease response: Progressive Disease; Progression or recurrence: Yes; Days to recurrence: 529 days (1.4 years).
- Follow-up contact recording only the day: day 1,880.

Other clinical attributes
- Weight: 77 kg; Height: 177 cm; BMI: 24.

Exposures
- Alcohol history: Yes; Alcohol intensity: Not Heavy Drinker.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3N-01656-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Biospecimen laterality: Right; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -16 days; Initial weight: 324 mg; Time between excision and freezing: 22 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3N-01656-21: Section location: Middle; Percent tumor nuclei: 85; Percent necrosis: 5.
- Sample C3N-01656-07: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Biospecimen laterality: Right; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -16 days; Initial weight: 551 mg; Time between excision and freezing: 22 minutes; Method of sample procurement: Surgical Resection; Diagnosis pathologically confirmed: Yes.
- Sample C3N-01656-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: -15 days; Method of sample procurement: Blood Draw.
